Somatic mutation profile of tumor specimen TCGA-KN-8429-01A (aliquot TCGA-KN-8429-01A-11D-2310-10) from TCGA case TCGA-KN-8429, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 38.1 years (13,903 days).
Specimen TCGA-KN-8429-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a653c3e1-9a3f-4692-bfff-6dec43648d3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8429-11A (Solid Tissue Normal), aliquot TCGA-KN-8429-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffcbed11-b8b0-4120-9601-b3cc4a245937

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0A4 | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs767146505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGN | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99642853; called by muse, mutect2
- ZNF653 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99542358; called by muse, mutect2
- ATP6V0A4 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC168 | c.9510G>T p.M3170I | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC11 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRIQ4 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- OR5D18 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2
- PPP1R3B | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 85/200 reads (43%) | called by muse, mutect2, varscan2
- RASGRF1 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 154/371 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RPH3A | c.1881C>G p.H627Q (on ENST00000389385 / NM_001143854.2; = p.H623Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- UNC79 | c.812C>A p.P271H (on ENST00000393151 / NM_001346218.2; = p.P94H on NM_020818.5) | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); called by muse, mutect2
- LGI2 | c.1128G>A p.A376= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as rs756467143, COSV66122507; called by muse, mutect2, varscan2
- SF1 | c.1809T>G p.P603= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs914759777; called by muse, mutect2, varscan2
- CLEC19A | chr16:19307650 G>A | 3'Flank (SNP) | VAF 25/63 reads (40%) | catalogued as rs202158142; called by muse, mutect2, varscan2
